Surgical pathology report (de-identified scan), TCGA case TCGA-91-6828, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-6828-01A (Primary Tumor).

[page 1 of 3]
Final Pathologic Diagnosis:

A. Lymph node, left level 9, excisional biopsy:

One lymph node, negative for malignancy (0/1).

B. Lung, left lower lobe, lobectomy:

Specimen: Left lower lobe of lung
Procedure: Lobectomy
Specimen laterality: Left
Tumor site: Lower lobe
Specimen integrity: Intact
Tumor size: 1.8 cm (greatest dimension)
Tumor focality: Unifocal
Tumor histologic type: Adenocarcinoma with cribriform architecture
Tumor grade: Moderately differentiated
Visceral pleura invasion: Absent
Tumor extension: Not applicable

Margins:

Bronchial: Negative
Vascular: Negative
Parenchymal: Negative
Parietal pleural: Not applicable
Chest wall: Not applicable

Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: >3 cm

Frozen section diagnosis is confirmed.

Specify margin: Bronchial/vascular
Treatment effect: Not applicable
Lymph-vascular invasion: Absent

Pathologic staging:

TNM descriptors: None
Primary tumor: pT1a
Regional lymph nodes: pN0
Number examined: 5
Number involved: 0
Distant metastasis: pM (not applicable)

Additional pathologic findings: One hilar lymph node, negative for malignancy (0/1), included in Synoptic Report above.

C. Lymph node, left level 5, excisional biopsy:

One lymph node, negative for malignancy (0/1).

D. Lymph node, left level 6, excisional biopsy:

[page 2 of 3]
One lymph node, negative for malignancy (0/1).

- E. Lymph node, left level 7, excisional biopsy:
One lymph node, negative for malignancy (0/1).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSB: (left lower lobe, diagnosis of mass):

Adenocarcinoma by [REDACTED]

Elapsed time: 15 minutes

Gross Description:

Received are five formalin-filled containers labeled with the patient's name.

Part A is received additionally labeled "A) level 9 lymph node." The specimen consists of a small fragment of tan-brown smooth to irregular soft tissue measuring 0.4 x 0.4 x 0.3 cm. The specimen is submitted in toto in cassette A.

Part B is received additionally labeled "B) left lower lobe." The specimen is initially received fresh. The specimen consists of a portion of lung measuring 13 x 11.5 x 4.5 cm. The pleural surface is purple-gray to tan and smooth with mild to moderate anthracosis. Serial sectioning reveals a well circumscribed firm tan mass measuring 1.8 x 1.4 x 1.4 cm and is located in the upper portion of the lower lobe. The mass is >3 cm from the bronchial and vascular margins. The remainder of the parenchyma is dark red to brown and congested. No other masses or lesions are identified. A portion of the mass is submitted for frozen section diagnosis. Residual frozen section tissue is submitted in cassette B1. A portion of the mass is also submitted to the Tissue Bank, as well as to diagnostics. The mass measures 0.5 cm from the pleural surface. No lymph nodes are identified.

Representative sections are submitted as follows:

- B1: Residual frozen section tissue
- B2: Bronchial margin
- B3: Vascular margin
- B4-8: Representative sections of mass
- B9: Uninvolved lung parenchyma

Part C is received additionally labeled "C) level 5 lymph node." The specimen consists of a small tan-brown irregular soft tissue fragment measuring 0.5 x 0.4 x 0.2 cm and is submitted in toto in cassette C.

Part D is received additionally labeled "D) level 6 lymph node." The specimen consists of a single tan-brown irregular soft tissue fragment measuring 0.4 x

[page 3 of 3]
0.3 x 0.2 cm and is submitted in toto in cassette D.

Part E is received additionally labeled "E) level 7 lymph node." The specimen consists of a single tan-brown irregular soft tissue fragment measuring 0.7 x 0.4 x 0.3 cm and is submitted in toto in cassette E.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Source: NCI Genomic Data Commons file 86c00dfa-db13-4d8f-a0c8-16964b5c0b52 (TCGA-91-6828.8B494F5F-5E6F-43BB-8748-0CB2D36EAB37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).